FM case AD7598 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/6f2742c4-f3c6-4db6-9f89-61cd39c0b2dc

Female, 55.2 years: Infiltrating duct carcinoma, NOS (ICD-O-3 8500/3) of the breast; metastasis biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
